CCDI case PBBWAA — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Eye and adnexa.
https://portal.gdc.cancer.gov/cases/4d9f71d4-6ad3-42ae-8c11-1bfe88036abb

Demographics
Sex at birth: female; Race: black or african american.

Diagnoses (1)
1. Retinoblastoma, NOS: ICD-O-3 morphology code: 9510/3; Tissue or organ of origin: Retina; Age at diagnosis: 0.9 years (318 days).

Biospecimens (3 samples)
- Sample 0DJE33: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DJE3B: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
- Sample 0DJE3H: Tissue type: Normal; Specimen type: Peripheral Whole Blood. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
